Somatic mutation profile of tumor specimen C3L-04791-04 (aliquot CPT0250310006) from CPTAC case C3L-04791, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 81.4 years (29,749 days).
Specimen C3L-04791-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8d1b9cf-dc56-4461-96b7-2ff33c9ee058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04791-31 (Blood Derived Normal), aliquot CPT0250450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1ce6ff0-2e46-4dd3-a926-28ba7ff4b582

The open-access MAF lists 591 somatic variants for this specimen: 417 protein-altering or splice-affecting, 104 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 104, Nonsense Mutation 30, Intron 30, 3'UTR 14, Splice Region 12, RNA 9, 5'UTR 8, 5'Flank 5, 3'Flank 4, Splice Site 4, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 94/393 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2684-1G>A p.X895_splice (on ENST00000272895 / NM_173076.3; = p.X577_splice on NM_015657.3) | Splice Site (SNP) | VAF 5/89 reads (6%) | catalogued as COSV55974149; called by muse, mutect2
- ADAMTS20 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101238990; called by muse, mutect2
- AFAP1L2 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV58419151; called by muse, mutect2, varscan2
- AIF1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.458); catalogued as COSV61962495; called by muse, mutect2, varscan2
- ALDH4A1 | c.1125C>G p.I375M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); catalogued as rs1456872299; called by muse, mutect2
- ALOX5 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV100979982; called by muse, mutect2
- ANK2 | c.4804G>A p.E1602K | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52178054; called by muse, mutect2
- ANK3 | c.5966G>A p.W1989* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV104383645; called by muse, mutect2, varscan2
- ANKZF1 | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1198701436; called by muse, mutect2, varscan2
- APC | c.8339G>C p.R2780T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57386229; called by muse, mutect2
- APC2 | c.4421G>A p.S1474N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1568181875; called by muse, mutect2
- ATP6V1B1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52270593; called by muse, mutect2, varscan2
- BPTF | c.7687C>G p.Q2563E | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.107); catalogued as COSV100075624; called by muse, mutect2
- C1QTNF7 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV54854060; called by muse, mutect2
- C1orf159 | c.181-4C>G | Splice Region (SNP) | VAF 28/420 reads (7%) | catalogued as rs1557749464; called by muse, mutect2
- CACNA1B | c.5292G>C p.K1764N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs762577612, COSV53123385; called by muse, mutect2, varscan2
- CATSPERG | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs944397745; called by muse, mutect2
- CCDC88C | c.2142G>C p.E714D | Missense Mutation (SNP) | VAF 59/412 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV101105360, COSV66242717; called by muse, mutect2, varscan2
- CDHR2 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs762232802; called by muse, mutect2, varscan2
- CDHR2 | c.2600C>G p.S867* | Nonsense Mutation (SNP) | VAF 16/432 reads (4%) | catalogued as COSV56138952; called by muse, mutect2
- CIZ1 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52975229; called by muse, mutect2
- COL16A1 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1330350490, COSV99594612; called by muse, mutect2, varscan2
- COTL1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1400415736; called by muse, mutect2, varscan2
- CRAMP1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as rs186357261; called by muse, mutect2, varscan2
- CTAGE15 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV101372105; called by muse, mutect2
- CTCF | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV50486390; called by muse, mutect2, varscan2
- CTDSPL2 | c.980G>C p.R327T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV52947540; called by muse, mutect2
- CUX2 | c.4268C>T p.S1423F | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV55648751; called by muse, mutect2, varscan2
- DAAM1 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.38); catalogued as COSV62839997; called by muse, mutect2
- DARS2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.904); catalogued as COSV53409445; called by muse, mutect2
- DGKE | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV52351719; called by muse, mutect2, varscan2
- DLGAP1 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 39/539 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59803581; called by muse, mutect2
- DNAJC18 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100122199; called by muse, mutect2
- DNTT | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64523448; called by muse, mutect2
- DOCK6 | c.5488G>C p.D1830H | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV99624642; called by muse, varscan2
- DOT1L | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.091); catalogued as rs1277215738; called by muse, mutect2
- DTX3L | c.1385G>A p.R462K | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99949947; called by muse, mutect2
- DVL2 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs1334291468; called by muse, mutect2, varscan2
- EFCAB6 | c.3556G>C p.E1186Q | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as COSV99414421; called by muse, mutect2
- ESPN | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs761160948; called by muse, mutect2
- EXOSC10 | c.1776G>C p.K592N | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV58664131; called by muse, mutect2
- FAM83A | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs892627305; called by muse, mutect2, varscan2
- FAM98C | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV53039299; called by muse, mutect2
- FHDC1 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV52599022; called by muse, mutect2
- FIP1L1 | c.689G>C p.R230T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV60997353; called by muse, mutect2, varscan2
- FLG2 | c.1765C>G p.Q589E | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV66174452; called by muse, mutect2
- FLRT2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as rs201758646; called by muse, mutect2, varscan2
- FOCAD | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100620276; called by muse, mutect2
- FTSJ3 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100037142; called by muse, mutect2
- FXYD4 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 31/439 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.782); catalogued as COSV72052621; called by muse, mutect2
- GABRA3 | c.1215C>G p.I405M | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV64798382; called by muse, mutect2, varscan2
- GDI2 | c.519G>C p.K173N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV66336273; called by muse, mutect2
- GIT2 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58080384; called by muse, mutect2, varscan2
- GP6 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59977086; called by muse, mutect2, varscan2
- GRID1 | c.2323C>A p.Q775K | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV60045441; called by muse, mutect2, varscan2
- GRM3 | c.630G>C p.W210C | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473869; called by muse, mutect2, varscan2
- GSE1 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 22/403 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs77405156, COSV99037308; called by muse, mutect2
- GSE1 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs984691309, COSV53676790, COSV99497247; called by muse, mutect2
- GTF2IRD1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as COSV99735781; called by muse, mutect2, varscan2
- HELZ | c.2175C>G p.L725= | Splice Region (SNP) | VAF 16/134 reads (12%) | catalogued as COSV62377400; called by muse, mutect2, varscan2
- HERC2 | c.9700T>G p.Y3234D | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV99871595; called by muse, mutect2
- HMCN1 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV54892425; called by muse, mutect2
- HSPB6 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs749817607; called by muse, mutect2
- IGF2R | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100807520; called by muse, mutect2
- IGHMBP2 | c.1129T>A p.C377S | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54821549; called by muse, mutect2
- IL27RA | c.1645G>C p.V549L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs754162060; called by muse, mutect2, varscan2
- ILDR1 | c.1444G>A p.E482K (on ENST00000344209 / NM_001199799.2; = p.E438K on NM_175924.4) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV99878064; called by muse, mutect2, varscan2
- KBTBD13 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs952061379; called by muse, mutect2
- KCNK13 | c.247C>G p.R83G | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1390458694, COSV99965452; called by muse, mutect2, varscan2
- KDM5C | c.1616C>G p.S539* | Nonsense Mutation (SNP) | VAF 13/274 reads (5%) | catalogued as COSV100948908; called by muse, mutect2
- KIAA1549 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs745323375, COSV54322989, COSV99650071; called by muse, mutect2, varscan2
- KIFC2 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs751667868; called by muse, mutect2
- KMT2D | c.4148del p.C1383Lfs*34 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | catalogued as COSV56410290; called by mutect2, pindel*
- KNL1 | c.5738G>A p.R1913Q (on ENST00000346991 / NM_170589.5; = p.R1887Q on NM_144508.5) | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1002149828; called by muse, mutect2, varscan2
- KRT31 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.401); catalogued as COSV52433997; called by muse, mutect2, varscan2
- KRTAP4-2 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs750863330; called by muse, mutect2, varscan2
- LACRT | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.328); catalogued as COSV99143910; called by muse, mutect2
- LDB3 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480550048; called by muse, mutect2
- LRRC30 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs754381996; called by muse, mutect2
- LRRTM4 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV101297406; called by muse, mutect2, varscan2
- MAP3K1 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV68125531; called by muse, mutect2
- MARK3 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551785219; called by muse, mutect2
- MCCD1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.058); catalogued as rs1231500876; called by muse, mutect2, varscan2
- MKI67 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV64075346; called by muse, mutect2, varscan2
- MLC1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 57/498 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs1196619166, COSV61115710; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV100825230; called by muse, mutect2
- MUC4 | c.10604C>T p.T3535M | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs773977719, COSV100206637; called by muse, mutect2, varscan2
- NAA25 | c.2111A>G p.N704S | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1283748821; called by muse, mutect2, varscan2
- NAAA | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | catalogued as rs1247817672; called by muse, mutect2
- NAALADL1 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 20/155 reads (13%) | catalogued as rs769506889; called by muse, mutect2, varscan2
- NDN | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59359620; called by muse, mutect2
- NEBL | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1379665942; called by muse, mutect2, varscan2
- NLGN4X | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52011605; called by muse, mutect2
- NOVA2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54356980; called by muse, varscan2
- NPS | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV67690513; called by muse, mutect2
- NR2F6 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV52243103; called by muse, mutect2, varscan2
- NUDT11 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs782555414, COSV65665288; called by muse, mutect2, varscan2
- OAS3 | c.2802C>A p.F934L | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57450221; called by muse, mutect2
- ORC3 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs375214415; called by muse, mutect2
- OTOF | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 16/171 reads (9%) | catalogued as COSV55514081; called by muse, mutect2
- P3H2 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1307588537, COSV60027650; called by muse, mutect2, varscan2
- PCK1 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs748682003, COSV60130976, COSV60131680; called by muse, mutect2, varscan2
- PLP2 | c.158C>G p.S53W | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV66239751; called by muse, mutect2, varscan2
- PNPLA7 | c.3446G>C p.R1149P | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52995595, COSV52998494; called by muse, mutect2, varscan2
- POLR3B | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs747108240, COSV57275577; called by muse, mutect2, varscan2
- POM121 | c.1421G>A p.R474K (on ENST00000434423; = p.R209K on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs17405659, COSV57514263; called by muse, mutect2
- POPDC3 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54645495, COSV99634096; called by muse, mutect2
- PPFIA2 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs369543017; called by muse, mutect2, varscan2
- PPIC | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 50/512 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1300719430; called by muse, mutect2
- PREP | c.1012C>G p.P338A (on ENST00000369110; = p.P404A on NM_002726.5) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64870078; called by muse, mutect2
- PRKCG | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 50/538 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54724561; called by muse, mutect2
- PRNP | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 71/606 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs1555782109, CM104613, COSV65173597; called by muse, mutect2, varscan2
- PRPF6 | c.2822_2824del p.F941del | In Frame Del (DEL) | VAF 33/235 reads (14%) | catalogued as rs747812103; called by mutect2, pindel, varscan2
- PSMD6 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV55759739; called by muse, mutect2, varscan2
- PTCHD3 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as COSV101438933; called by muse, mutect2
- PTPN18 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1297372224; called by muse, mutect2, varscan2
- PTPRC | c.3158G>C p.R1053T | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100722441; called by muse, mutect2
- RASSF6 | c.244G>A p.E82K (on ENST00000342081 / NM_201431.2; = p.E50K on NM_177532.5) | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1205412024; called by muse, mutect2
- RBM20 | c.3309G>C p.L1103F | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.522); catalogued as COSV65707701; called by muse, mutect2
- RFX6 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV60584494; called by muse, mutect2
- RNF146 | c.307G>A p.E103K (on ENST00000368314 / NM_001242850.2; = p.E102K on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as rs748283283; called by muse, mutect2
- RPRD2 | c.2803G>C p.D935H | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs1212462464; called by muse, varscan2
- SBF2 | c.4465G>A p.E1489K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs864622502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC63 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs776218043; called by muse, mutect2, varscan2
- SFMBT2 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 56/444 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.633); catalogued as COSV100738814; called by muse, mutect2, varscan2
- SHISAL2B | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as rs898489184; called by muse, mutect2
- SIRPD | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as rs1285502032, COSV67546543; called by muse, mutect2, varscan2
- SLC6A4 | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | catalogued as COSV99911377; called by muse, mutect2
- SLC7A8 | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.803); catalogued as rs752814137; called by muse, mutect2, varscan2
- SORCS1 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.878); catalogued as COSV99548654; called by muse, mutect2, varscan2
- SORCS1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53876887; called by muse, mutect2, varscan2
- SOWAHB | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764064193; called by muse, mutect2
- SPEN | c.3665C>G p.S1222C | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV65359224; called by muse, mutect2
- SPINT2 | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); catalogued as rs776367740; called by muse, mutect2
- SYDE1 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs748308086; called by muse, mutect2, varscan2
- SYN1 | c.1147C>G p.H383D | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55983568; called by muse, mutect2, varscan2
- SZT2 | c.9041G>A p.R3014Q (on ENST00000634258 / NM_001365999.1; = p.R2957Q on NM_015284.4) | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755302772, COSV100981301; called by muse, mutect2
- TAMALIN | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | catalogued as rs1409465595; called by muse, mutect2, varscan2
- TBXT | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs143094140; called by muse, mutect2
- TCEA3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71531954; called by muse, varscan2
- TDO2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs745696595, COSV72232584; called by muse, mutect2, varscan2
- TGM5 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 111/482 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as rs546033974, COSV55009996; called by muse, mutect2, varscan2
- THBS3 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs776932313; called by muse, mutect2
- THSD7A | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs767395309, COSV70273978; called by muse, mutect2, varscan2
- TMC1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV52784020; called by muse, mutect2
- TNS4 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV54189046; called by muse, mutect2, varscan2
- TOR4A | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs879817809; called by muse, mutect2, varscan2
- TPRG1L | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1351967285; called by muse, mutect2
- TRIM42 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs745861203, COSV53885591; called by muse, mutect2
- TRIM67 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 36/439 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1357084083; called by muse, mutect2
- TRPC5 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53288291; called by muse, mutect2, varscan2
- TTYH1 | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs201121658; called by muse, mutect2, varscan2
- USP33 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as COSV62470783; called by muse, mutect2
- VCAN | c.5959G>A p.E1987K | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs1236770305; called by muse, mutect2, varscan2
- VWA5A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs999128670, COSV63707848; called by muse, mutect2
- WDR64 | c.2484G>C p.R828S | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV63793790; called by muse, mutect2
- ZBTB7B | c.310G>A p.E104K (on ENST00000292176; = p.E138K on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV52692915, COSV52693144; called by muse, mutect2
- ZFHX3 | c.6169C>T p.Q2057* | Nonsense Mutation (SNP) | VAF 16/165 reads (10%) | catalogued as COSV51709979; called by muse, mutect2
- ZFP36 | c.567G>C p.Q189H (on ENST00000594442; = p.Q183H on NM_003407.5) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1424270776; called by muse, mutect2
- ZFP36L2 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 54/580 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV56697423, COSV56700013; called by muse, mutect2
- ZNF462 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 26/491 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as COSV52931026; called by muse, mutect2
- ZNF485 | c.837C>G p.F279L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100700272; called by muse, mutect2
- ZNF599 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1472009250; called by muse, mutect2
- ZNFX1 | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs751232357; called by muse, mutect2
- ACCS | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2
- ADGB | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRB2 | c.4102G>T p.G1368* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | called by muse, varscan2
- AKAP12 | c.4859C>T p.S1620L | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALDH6A1 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- ALG11 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 21/528 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- ALG3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALK | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.364); called by muse, mutect2
- ALPK1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- AMIGO2 | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARHGAP24 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.102); called by muse, mutect2
- ARID1A | c.5103C>G p.I1701M | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ATP2A3 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- AVPR1A | c.765G>C p.Q255H | Missense Mutation (SNP) | VAF 9/303 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- BOD1L1 | c.7486G>A p.E2496K | Missense Mutation (SNP) | VAF 23/329 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- BRMS1 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- BTAF1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- C1R | c.472G>A p.D158N (on ENST00000536053 / NM_001354346.2; = p.D144N on NM_001733.7) | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- C1S | c.871+3G>C | Splice Region (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- C1orf198 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.7); called by muse, varscan2
- C1orf35 | c.447+6C>T | Splice Region (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- C6orf132 | c.2060C>G p.S687C | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); called by muse, mutect2
- CACNA1A | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CACNA1A | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2
- CACNG6 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALML5 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 35/435 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- CAMTA2 | c.2615C>A p.S872Y | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2
- CAPG | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CASP8 | c.1249G>T p.E417* (on ENST00000432109 / NM_033355.3; = p.E434* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2
- CCDC141 | c.2476C>T p.H826Y | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CCDC97 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 60/439 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CDH10 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- CELSR2 | c.7815C>G p.I2605M | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CENPE | c.5548G>C p.E1850Q | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2
- CENPS-CORT | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2
- CEP162 | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHRNA2 | c.801C>G p.F267L | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CLPX | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CNTN2 | c.2217G>C p.Q739H | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.147); called by muse, mutect2
- COASY | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 39/346 reads (11%) | called by muse, mutect2, varscan2
- COL24A1 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CPNE6 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- CR1 | c.1708G>C p.D570H (on ENST00000367051; = p.D1020H on NM_000651.6) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- CR2 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CROCC | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 32/834 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- CROCC2 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- CSDE1 | c.2154G>C p.E718D (on ENST00000358528 / NM_001007553.3; = p.E687D on NM_007158.6) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- CTAGE8 | c.738A>G p.I246M | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.135); called by mutect2, varscan2
- CTDP1 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CTR9 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CYP8B1 | c.492G>C p.W164C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAB2IP | c.1424G>A p.C475Y (on ENST00000408936; = p.C447Y on NM_032552.3) | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDX17 | c.1035A>T p.Q345H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- DLX2 | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- DNAJB1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DPP6 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2
- DYNC2H1 | c.5845G>C p.E1949Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2
- EFCAB7 | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- ELP5 | c.126G>C p.L42F | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERRFI1 | c.126-3C>T | Splice Region (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- EVX1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 36/560 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- EXOC3L1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EZH2 | c.1433C>T p.A478V (on ENST00000460911 / NM_001203247.2; = p.A483V on NM_004456.5) | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.027); called by muse, mutect2
- F3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- FAM153A | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- FAM153B | c.685C>T p.Q229* (on ENST00000253490; = p.Q152* on NM_001265615.1) | Nonsense Mutation (SNP) | VAF 18/524 reads (3%) | called by muse, mutect2
- FAM193B | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- FAM221B | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.157); called by muse, mutect2
- FAT1 | c.10609G>A p.E3537K | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- FBXO46 | c.1154C>G p.T385S | Missense Mutation (SNP) | VAF 29/431 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.196); called by muse, mutect2
- FEZF1 | c.928C>G p.H310D | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLG2 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLG2 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2
- FLG2 | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- FMR1 | c.270+8A>G | Splice Region (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- FOXO1 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- FREM2 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCM2 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 82/506 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GFPT1 | c.1307T>C p.F436S (on ENST00000357308 / NM_001244710.2; = p.F418S on NM_002056.4) | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIN1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by mutect2, varscan2
- GLI1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2
- GLI4 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 27/464 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.046); called by muse, mutect2
- GNL1 | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GON4L | c.6649G>T p.D2217Y | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOSR2 | c.172G>A p.D58N (on ENST00000393456 / NM_001321134.1; = p.D76N on NM_004287.5) | Missense Mutation (SNP) | VAF 37/432 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- GPIHBP1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 64/923 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- GREB1L | c.3677C>T p.A1226V | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- GSDMC | c.221-1G>C p.X74_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- GTF2I | c.2780G>C p.R927T (on ENST00000573035 / NM_032999.4; = p.R886T on NM_001518.5) | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GXYLT1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC7 | c.2589+3G>A | Splice Region (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- HDHD3 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- HDLBP | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECTD1 | c.2267G>C p.G756A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- HERC1 | c.8395G>A p.E2799K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2
- HMGCS2 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); called by muse, mutect2
- HSD11B1 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 39/338 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- HSP90B1 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- HYDIN | c.14046G>C p.Q4682H | Missense Mutation (SNP) | VAF 79/622 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ICAM5 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- IFIH1 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- IGHE | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHMBP2 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- JKAMP | c.802C>T p.L268F (on ENST00000554271 / NM_001284201.1; = p.L254F on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KALRN | c.5817G>C p.Q1939H (on ENST00000360013 / NM_001024660.4; = p.Q242H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KCNG1 | c.1391C>G p.S464C | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KCNH5 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCTD14 | c.559T>G p.C187G | Missense Mutation (SNP) | VAF 35/385 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- KDM5C | c.4495G>C p.E1499Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA0586 | c.2838G>C p.Q946H (on ENST00000619416 / NM_001244190.2; = p.Q885H on NM_014749.5) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KLHL21 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 19/552 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.258); called by muse, mutect2
- KRT6A | c.1581C>A p.F527L | Missense Mutation (SNP) | VAF 52/758 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.087); called by muse, mutect2
- LAMB2 | c.4574-1G>C p.X1525_splice | Splice Site (SNP) | VAF 34/380 reads (9%) | called by muse, mutect2
- LMF2 | c.1606+6dup | Splice Region (INS) | VAF 11/98 reads (11%) | called by mutect2, pindel
- LRRC49 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MAP7D1 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2
- MATR3 | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- MDGA2 | c.2187G>A p.M729I (on ENST00000399232 / NM_001113498.2; = p.M431I on NM_182830.4) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.06); called by muse, mutect2
- MDM1 | c.669C>G p.F223L | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2
- MECOM | c.967C>T p.P323S (on ENST00000468789 / NM_001105078.4; = p.P511S on NM_004991.4) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2
- MED12L | c.5115G>T p.E1705D | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MELK | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL2B | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 19/306 reads (6%) | called by muse, mutect2
- MIB1 | c.2377C>G p.H793D | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); called by muse, varscan2
- MLLT6 | c.110-3C>G | Splice Region (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- MMP13 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2
- MOGS | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.096); called by muse, mutect2
- MRM1 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MSH4 | c.2068T>G p.L690V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2
- MUC12 | c.15789G>C p.M5263I (on ENST00000379442; = p.M5120I on NM_001164462.1) | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.03); called by muse, mutect2
- N4BP1 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAPH2 | c.1643A>T p.E548V | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFS2 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 16/423 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- NEK9 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); called by muse, mutect2
- NKD1 | c.1352G>C p.R451T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NOTCH1 | c.6839C>G p.S2280C | Missense Mutation (SNP) | VAF 50/672 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); called by muse, mutect2
- NT5C3B | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by mutect2, varscan2
- NTRK2 | c.2298C>G p.I766M (on ENST00000323115 / NM_001369534.1; = p.I782M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP107 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- NUTM1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.906); called by muse, mutect2
- OBSL1 | c.5261G>A p.G1754E | Missense Mutation (SNP) | VAF 41/526 reads (8%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.958); called by muse, mutect2
- OCA2 | c.1629G>C p.E543D | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2
- OR8B2 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- P4HA2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCDHGC4 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by muse, mutect2
- PCF11 | c.2791G>C p.D931H | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2
- PCSK6 | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCYOX1 | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PDHA2 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDXDC1 | c.1141-7C>T | Splice Region (SNP) | VAF 12/197 reads (6%) | called by muse, mutect2
- PIGO | c.2789C>G p.S930C | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- PIPOX | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2
- PLAGL2 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- PLEC | c.616G>C p.D206H (on ENST00000322810 / NM_201380.4; = p.D96H on NM_000445.5) | Missense Mutation (SNP) | VAF 62/720 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEC | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2
- PLEKHD1 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.149); called by muse, mutect2
- POMP | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2
- POU4F3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 62/450 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPFIA4 | c.2806C>G p.Q936E (on ENST00000447715; = p.Q937E on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.359); called by muse, mutect2
- PRB2 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, varscan2
- PRDM16 | c.2970C>G p.I990M | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- PRDM2 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 35/794 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- PRLR | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.341); called by muse, mutect2
- PRR9 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 35/311 reads (11%) | called by muse, mutect2, varscan2
- PSMF1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PTPN21 | c.3247G>C p.E1083Q | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- QPCTL | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- RAB2B | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); called by muse, mutect2
- RABGGTA | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASEF | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- RBM27 | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- RC3H2 | c.2988G>C p.K996N | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.61); called by muse, mutect2
- RERE | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 35/661 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RPL5 | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RPRD2 | c.2756G>C p.R919T | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, varscan2
- RRP1B | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2
- RSBN1L | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- RTL5 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SAMD4B | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCRN3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- SDC4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2
- SEL1L | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SERPINA9 | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- SFXN4 | c.491G>T p.R164I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- SGK1 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK3 | c.5023C>G p.L1675V | Missense Mutation (SNP) | VAF 76/737 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2
- SHC1 | c.1100G>A p.R367K (on ENST00000368445 / NM_183001.5; = p.R257K on NM_003029.5) | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- SHOC1 | c.3098C>G p.S1033C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SHOC2 | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- SIN3A | c.3538A>C p.I1180L | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SIPA1L1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- SIPA1L1 | c.4345C>T p.H1449Y | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.943); called by muse, mutect2
- SKIL | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC30A1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2
- SLC6A2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SMC2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.377); called by muse, mutect2
- SMG7 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- SMPDL3B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/192 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SNAPC4 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA2L | c.1214T>G p.L405W | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SPIDR | c.2604+5G>C | Splice Region (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- SPTBN4 | c.4921G>C p.E1641Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- SRBD1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- STARD9 | c.5579C>G p.S1860C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- SUCLA2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- TACC2 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAX1BP1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.401); called by muse, mutect2
- TBC1D10C | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 55/530 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TBX20 | c.655-1G>A p.X219_splice | Splice Site (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- TCF25 | c.1800-3C>G | Splice Region (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- TCP11L1 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TENM2 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2
- TMEM131 | c.3064G>C p.E1022Q | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM135 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 52/550 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, mutect2
- TMEM245 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- TMEM256 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- TMEM98 | c.26T>C p.I9T | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM24 | c.3058G>C p.E1020Q (on ENST00000343526 / NM_015905.3; = p.E986Q on NM_003852.4) | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by muse, mutect2
- TRIM51 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2
- TRPS1 | c.118G>A p.D40N (on ENST00000220888 / NM_001330599.2; = p.D53N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); called by muse, mutect2
- TTC13 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 44/412 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, varscan2
- TTC28 | c.6163G>C p.E2055Q | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- UBE2D1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- UBQLN1 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- UBR4 | c.8413G>A p.D2805N | Missense Mutation (SNP) | VAF 28/489 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- UNC119B | c.81G>C p.K27N | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UNC13B | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 14/422 reads (3%) | called by muse, mutect2
- UNC13B | c.2784G>C p.L928F | Missense Mutation (SNP) | VAF 20/509 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- UNC13B | c.4114G>A p.G1372R | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- UNC13C | c.4084C>T p.Q1362* | Nonsense Mutation (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- UNC5D | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- USP27X | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VAPA | c.339G>C p.W113C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VDAC2 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- VPS13D | c.11448G>C p.Q3816H | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- VSIG10L | c.2487G>C p.K829N | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, varscan2
- VWA5B2 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.115); called by muse, mutect2
- WDFY4 | c.5122C>G p.L1708V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- WFDC12 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 25/289 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); called by muse, mutect2
- WWP2 | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 19/326 reads (6%) | called by muse, mutect2
- XAB2 | c.912G>C p.E304D | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2
- YDJC | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF20 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ZNF215 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF37A | c.1523C>G p.S508* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- ZNF417 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2
- ZNF429 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZNF462 | c.1982C>G p.S661* | Nonsense Mutation (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- ZNF484 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF695 | c.706G>T p.G236* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- ABHD17C | c.408C>T p.L136= | Silent (SNP) | VAF 60/596 reads (10%) | called by muse, mutect2, varscan2
- ABHD8 | c.448C>A p.R150= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as COSV53112612; called by muse, mutect2, varscan2
- ACIN1 | c.1545G>A p.Q515= | Silent (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- ARHGAP25 | c.393C>A p.L131= (on ENST00000409202 / NM_001007231.3; = p.L124= on NM_014882.3) | Silent (SNP) | VAF 19/324 reads (6%) | called by muse, mutect2
- ATCAY | c.303C>T p.P101= | Silent (SNP) | VAF 29/187 reads (16%) | catalogued as rs564953293; called by muse, mutect2, varscan2
- ATP13A2 | c.3465C>G p.S1155= | Silent (SNP) | VAF 50/948 reads (5%) | called by muse, mutect2
- ATP8B4 | c.1419C>G p.L473= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs761916821, COSV52719389, COSV52722315; called by muse, mutect2, varscan2
- BATF | c.36C>T p.F12= | Silent (SNP) | VAF 29/362 reads (8%) | called by muse, mutect2
- BCAR1 | c.2612G>A p.*871= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- BHLHE23 | c.456C>A p.L152= (on ENST00000370346; = p.L168= on NM_080606.4) | Silent (SNP) | VAF 60/557 reads (11%) | called by muse, mutect2
- CASS4 | c.252G>C p.L84= | Silent (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- CCDC151 | c.429G>A p.K143= | Silent (SNP) | VAF 26/280 reads (9%) | catalogued as COSV52952787; called by muse, mutect2
- CCDC88B | c.489C>T p.L163= | Silent (SNP) | VAF 26/312 reads (8%) | catalogued as COSV57264994; called by muse, mutect2
- CDHR3 | c.1971G>A p.L657= | Silent (SNP) | VAF 31/256 reads (12%) | catalogued as rs1359897707; called by muse, mutect2, varscan2
- CHD3 | c.4686G>A p.E1562= | Silent (SNP) | VAF 15/177 reads (8%) | called by muse, mutect2
- CHSY3 | c.1407G>A p.L469= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV59287763; called by muse, mutect2, varscan2
- COG3 | c.72C>T p.L24= | Silent (SNP) | VAF 31/430 reads (7%) | catalogued as rs1310278721, COSV100596386; called by muse, mutect2
- COL8A2 | c.249G>A p.G83= | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- CP | c.885C>T p.H295= | Silent (SNP) | VAF 23/253 reads (9%) | catalogued as rs766821938, COSV99223963; ClinVar: likely benign; called by muse, mutect2
- CPT1B | c.366C>T p.F122= | Silent (SNP) | VAF 36/350 reads (10%) | catalogued as rs1017646306, COSV100376884; called by muse, mutect2, varscan2
- CROCC | c.2181G>A p.L727= | Silent (SNP) | VAF 24/482 reads (5%) | called by muse, mutect2
- CXXC4 | c.687C>T p.L229= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as rs769208271; called by muse, mutect2
- CYHR1 | c.984G>A p.E328= | Silent (SNP) | VAF 21/396 reads (5%) | catalogued as rs1351980188; called by muse, mutect2
- CYP2A13 | c.1233C>T p.F411= | Silent (SNP) | VAF 26/384 reads (7%) | catalogued as COSV57837583; called by muse, mutect2
- DAGLA | c.1575C>T p.L525= | Silent (SNP) | VAF 26/202 reads (13%) | catalogued as rs766345907, COSV57196065, COSV57197118; called by muse, mutect2, varscan2
- DBF4 | c.708G>A p.L236= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- DHODH | c.837G>A p.L279= | Silent (SNP) | VAF 29/583 reads (5%) | called by muse, mutect2
- DISP1 | c.2919C>T p.F973= | Silent (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- DNAH7 | c.5715C>T p.V1905= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs772642319, COSV56776384; called by muse, mutect2, varscan2
- DPYSL3 | c.1044C>T p.F348= | Silent (SNP) | VAF 15/220 reads (7%) | called by muse, mutect2
- EIF3B | c.2109G>C p.L703= | Silent (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- ENG | c.582C>T p.L194= | Silent (SNP) | VAF 30/418 reads (7%) | catalogued as rs140663846, CX065866; ClinVar: likely benign; called by muse, mutect2
- ENTPD5 | c.540G>A p.V180= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV58224222; called by muse, mutect2
- FLT4 | c.3912G>A p.Q1304= | Silent (SNP) | VAF 24/399 reads (6%) | called by muse, mutect2
- FN1 | c.5955G>C p.L1985= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as COSV60557132; called by muse, mutect2
- FRAT2 | c.529C>A p.R177= | Silent (SNP) | VAF 49/413 reads (12%) | catalogued as COSV64017301; called by muse, mutect2, varscan2
- GON4L | c.309C>T p.I103= | Silent (SNP) | VAF 29/220 reads (13%) | catalogued as COSV99673761; called by muse, mutect2, varscan2
- GPRIN1 | c.2739G>A p.V913= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- GZMB | c.171C>T p.D57= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1433844780; called by muse, mutect2
- HCAR1 | c.372G>A p.V124= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- HCN4 | c.1137C>T p.F379= | Silent (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- HHIPL1 | c.237G>A p.A79= | Silent (SNP) | VAF 21/219 reads (10%) | called by muse, mutect2
- HSPG2 | c.6981G>T p.G2327= | Silent (SNP) | VAF 46/730 reads (6%) | called by muse, mutect2
- HUWE1 | c.357G>A p.L119= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs1448579263; called by muse, mutect2, varscan2
- IBTK | c.2640G>A p.L880= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- IFT43 | c.351G>A p.Q117= (on ENST00000314067 / NM_001102564.3; = p.Q122= on NM_052873.3) | Silent (SNP) | VAF 25/328 reads (8%) | called by muse, mutect2
- INSR | c.720G>C p.L240= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- IRS4 | c.3378G>C p.P1126= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- KIF1A | c.4005C>A p.L1335= (on ENST00000320389 / NM_001379639.1; = p.L1327= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 42/420 reads (10%) | catalogued as COSV57495144; called by muse, mutect2
- KLHL15 | c.168C>T p.F56= | Silent (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- LAMC2 | c.2814G>C p.L938= | Silent (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- LRP4 | c.1599G>A p.S533= | Silent (SNP) | VAF 43/306 reads (14%) | catalogued as rs745607132; called by muse, mutect2, varscan2
- LRRC26 | c.321G>A p.L107= | Silent (SNP) | VAF 91/732 reads (12%) | called by muse, mutect2, varscan2
- MAP1LC3A | c.105C>T p.I35= | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, varscan2
- MAP6 | c.303G>C p.R101= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1035520001; called by mutect2, varscan2
- MARCHF8 | c.597T>A p.T199= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- MEF2A | c.447C>T p.P149= (on ENST00000557942 / NM_001319206.2; = p.P151= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- MFSD10 | c.909C>T p.F303= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as rs761441745; called by muse, mutect2, varscan2
- MIS18BP1 | c.1365C>T p.L455= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- MLXIPL | c.96G>C p.P32= | Silent (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
- NDUFC1 | c.126G>A p.L42= | Silent (SNP) | VAF 28/304 reads (9%) | catalogued as rs1330139381; called by muse, mutect2
- NES | c.684C>G p.L228= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as COSV100957778; called by muse, mutect2
- NFE2L3 | c.1027C>T p.L343= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2
- NIN | c.2562G>A p.E854= | Silent (SNP) | VAF 13/185 reads (7%) | called by muse, mutect2
- NLRX1 | c.747C>G p.L249= | Silent (SNP) | VAF 24/344 reads (7%) | catalogued as COSV52701749, COSV52706148; called by muse, mutect2
- NOMO2 | c.1005C>G p.V335= | Silent (SNP) | VAF 13/110 reads (12%) | called by mutect2, varscan2
- NPAS1 | c.96G>C p.L32= | Silent (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- OR4K17 | c.90C>T p.L30= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- PARP10 | c.1254G>A p.E418= | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as COSV57299911; called by muse, mutect2
- PCSK6 | c.429G>A p.V143= | Silent (SNP) | VAF 24/326 reads (7%) | catalogued as rs773902223; called by muse, mutect2
- PDCD6IP | c.561C>T p.L187= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs770845093; called by muse, mutect2, varscan2
- PHYHIP | c.978C>T p.I326= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- PIAS4 | c.1320G>C p.G440= | Silent (SNP) | VAF 71/652 reads (11%) | called by muse, mutect2, varscan2
- POLR3A | c.3990C>T p.D1330= | Silent (SNP) | VAF 60/475 reads (13%) | catalogued as rs201875398, COSV64931137, COSV64932348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAM1 | c.1863C>T p.F621= | Silent (SNP) | VAF 41/290 reads (14%) | called by muse, mutect2, varscan2
- PSTK | c.114C>T p.L38= | Silent (SNP) | VAF 37/449 reads (8%) | catalogued as COSV64398129; called by muse, mutect2
- RGS11 | c.961C>T p.L321= (on ENST00000397770 / NM_183337.3; = p.L300= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/184 reads (10%) | catalogued as rs751421579; called by muse, mutect2
- RIOK3 | c.930C>T p.F310= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV100259479; called by muse, mutect2
- RNF38 | c.942C>G p.L314= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- ROCK1 | c.1044C>T p.L348= | Silent (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- RSPH14 | c.600C>T p.L200= | Silent (SNP) | VAF 42/539 reads (8%) | catalogued as COSV53268596; called by muse, mutect2
- SCAP | c.1017G>C p.L339= | Silent (SNP) | VAF 26/230 reads (11%) | called by muse, mutect2, varscan2
- SCN4A | c.2568C>T p.L856= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as rs1393708864; called by muse, mutect2, varscan2
- SERPINB2 | c.438G>A p.Q146= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.1149C>T p.L383= (on ENST00000369774 / NM_001365079.1; = p.L355= on NM_014631.2) | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- SIN3A | c.3537G>C p.V1179= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- SLC29A2 | c.633G>C p.L211= | Silent (SNP) | VAF 47/565 reads (8%) | called by muse, mutect2
- SLC6A18 | c.234C>T p.I78= | Silent (SNP) | VAF 44/396 reads (11%) | catalogued as rs141321317; called by mutect2, varscan2
- SYNE1 | c.16548G>A p.E5516= (on ENST00000367255 / NM_182961.4; = p.E5445= on NM_033071.3) | Silent (SNP) | VAF 20/299 reads (7%) | called by muse, mutect2
- TBXAS1 | c.651C>T p.F217= | Silent (SNP) | VAF 81/634 reads (13%) | catalogued as rs779201611, COSV54950392; called by muse, mutect2, varscan2
- TF | c.39C>T p.V13= | Silent (SNP) | VAF 70/682 reads (10%) | called by muse, mutect2, varscan2
- TMEM196 | c.366C>T p.S122= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs1218259368, COSV101337517; called by muse, mutect2, varscan2
- TRRAP | c.981C>T p.L327= | Silent (SNP) | VAF 13/172 reads (8%) | called by muse, mutect2
- TUBA3D | c.1185C>T p.F395= | Silent (SNP) | VAF 39/461 reads (8%) | catalogued as rs753379663; called by muse, mutect2
- TXNDC11 | c.525G>A p.Q175= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- UNC13C | c.6516G>A p.L2172= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as COSV52878531; called by muse, mutect2
- UNC13D | c.1563C>G p.L521= | Silent (SNP) | VAF 83/545 reads (15%) | catalogued as COSV52883209; called by muse, mutect2, varscan2
- USP24 | c.1992G>A p.K664= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV53765254, COSV53765511; called by muse, mutect2, varscan2
- VDAC1 | c.172C>T p.L58= | Silent (SNP) | VAF 33/301 reads (11%) | called by muse, mutect2, varscan2
- WDR24 | c.2388G>A p.K796= (on ENST00000248142; = p.K666= on NM_032259.4) | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs142550128; called by muse, mutect2, varscan2
- XDH | c.3870C>T p.N1290= | Silent (SNP) | VAF 25/253 reads (10%) | catalogued as rs774319963, COSV101052003; called by muse, mutect2, varscan2
- ZBTB46 | c.1374C>T p.R458= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV99829783; called by mutect2, varscan2
- ZNF705A | c.870G>A p.G290= | Silent (SNP) | VAF 15/165 reads (9%) | catalogued as rs1438483005; called by muse, mutect2, varscan2
- ZNF710 | c.1098C>G p.L366= | Silent (SNP) | VAF 21/246 reads (9%) | called by muse, mutect2
- AC084082.1 | n.281G>A | RNA (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2, varscan2
- AC245033.1 | c.155-4234G>C | Intron (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- AL353804.6 | chrX:73827593 C>G | 3'Flank (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- AP001496.2 | n.890C>T | RNA (SNP) | VAF 38/280 reads (14%) | called by muse, mutect2, varscan2
- AP3B2 | c.360+238G>T | Intron (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- ARHGEF4 | c.39+598C>T | Intron (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- BRMS1 | c.693+210G>T | Intron (SNP) | VAF 11/61 reads (18%) | catalogued as rs554925941; called by muse, mutect2, varscan2
- C1QTNF3 | c.351+13C>T | Intron (SNP) | VAF 11/114 reads (10%) | catalogued as rs370798197; called by muse, mutect2
- C1orf21 | c.190-22259G>A | Intron (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- C22orf34 | n.2092G>C | RNA (SNP) | VAF 27/285 reads (9%) | catalogued as rs1232859180; called by muse, mutect2
- CDH15 | chr16:89168756 G>C | 5'Flank (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- CHMP1A | c.7+38G>A | Intron (SNP) | VAF 30/404 reads (7%) | catalogued as rs764222059; called by muse, mutect2
- CHST15 | c.*1172G>C | 3'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- CLN5 | chr13:76992013 C>G | 5'Flank (SNP) | VAF 57/483 reads (12%) | catalogued as rs988786332; called by muse, mutect2, varscan2
- COL18A1-AS2 | chr21:45405436 C>T | 3'Flank (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2
- DAAM2 | c.*2659A>G | 3'UTR (SNP) | VAF 25/134 reads (19%) | catalogued as rs865895422; called by muse, mutect2, varscan2
- DMXL2 | c.7923+36C>G | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- FUBP1 | c.1345-17C>G | Intron (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- GPRC5B | c.*17G>C | 3'UTR (SNP) | VAF 10/71 reads (14%) | catalogued as rs777261121, COSV100244727; called by muse, mutect2, varscan2
- HERC2P3 | n.1421G>A | RNA (SNP) | VAF 40/943 reads (4%) | catalogued as rs779514624; called by muse, mutect2
- HSDL2 | c.-14G>A | 5'UTR (SNP) | VAF 26/389 reads (7%) | called by muse, mutect2
- INPP5F | c.612+22G>T | Intron (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701695 C>G | 3'Flank (SNP) | VAF 34/147 reads (23%) | catalogued as rs1208666723; called by muse, mutect2, varscan2
- KRT6A | c.*34C>G | 3'UTR (SNP) | VAF 12/163 reads (7%) | catalogued as COSV100417019; called by muse, mutect2
- LINC00587 | n.137C>G | RNA (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- LINC02740 | n.235G>A | RNA (SNP) | VAF 14/128 reads (11%) | called by muse, varscan2
- MBD3 | c.*5+46G>A | Intron (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- MEIS1 | c.*310C>A | 3'UTR (SNP) | VAF 32/238 reads (13%) | called by muse, mutect2, varscan2
- MGAT4EP | n.1446C>T | RNA (SNP) | VAF 40/418 reads (10%) | called by muse, mutect2
- MRPL3 | c.-145G>C | 5'UTR (SNP) | VAF 20/192 reads (10%) | catalogued as COSV53915989; called by muse, mutect2, varscan2
- MTX1 | chr1:155215735 C>T | 3'Flank (SNP) | VAF 80/582 reads (14%) | called by muse, mutect2, varscan2
- NARF | c.770-470G>A | Intron (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- NRXN2 | c.1197+58C>G | Intron (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2
- NT5C1B-RDH14 | c.*166A>G | 3'UTR (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- P3H4 | c.*45G>A | 3'UTR (SNP) | VAF 14/240 reads (6%) | catalogued as rs782341621, COSV62680205; called by muse, mutect2
- PARN | chr16:14632471 G>C | 5'Flank (SNP) | VAF 19/202 reads (9%) | called by muse, mutect2
- PGAP6 | chr16:386819 G>A | 5'Flank (SNP) | VAF 37/357 reads (10%) | catalogued as rs746990132; called by muse, mutect2, varscan2
- PRKAR1B | c.178-10840G>A | Intron (SNP) | VAF 37/323 reads (11%) | catalogued as rs1562344155; called by muse, mutect2, varscan2
- RHBDD2 | c.*52G>A | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- RPL11 | c.-1C>T | 5'UTR (SNP) | VAF 56/509 reads (11%) | catalogued as rs760781404; called by muse, mutect2, varscan2
- RTN3 | c.2531-3041C>G | Intron (SNP) | VAF 10/71 reads (14%) | catalogued as rs754028587; called by muse, mutect2
- RUNX1T1 | c.88+13285G>A | Intron (SNP) | VAF 15/164 reads (9%) | catalogued as rs1455449550, COSV56138976; called by muse, mutect2
- SCN4B | c.*740G>C | 3'UTR (SNP) | VAF 10/350 reads (3%) | called by muse, mutect2
- SDC1 | c.66+609G>C | Intron (SNP) | VAF 39/363 reads (11%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1032-114G>C | Intron (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- SLC41A3 | c.274-5450G>A | Intron (SNP) | VAF 24/222 reads (11%) | catalogued as rs367939630; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23780G>A | Intron (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- SMARCA2 | c.3982-1850G>T | Intron (SNP) | VAF 41/201 reads (20%) | catalogued as COSV56646400; called by muse, mutect2, varscan2
- SMPX | c.*260G>A | 3'UTR (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- SNORD115-12 | n.44G>A | RNA (SNP) | VAF 26/516 reads (5%) | called by muse, mutect2
- SON | c.6321+253G>C | Intron (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2
- SRCIN1 | c.22+1103C>T | Intron (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.12245G>T | RNA (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.-16G>C | 5'UTR (SNP) | VAF 28/358 reads (8%) | catalogued as COSV100231629; called by muse, mutect2
- STK16 | c.87-131C>G | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- STK35 | c.*71C>G | 3'UTR (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- STMN2 | c.481-1190C>G | Intron (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- STRA6 | c.*37G>A | 3'UTR (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- SYNE2 | c.19333+882C>T | Intron (SNP) | VAF 23/422 reads (5%) | catalogued as rs773806326; called by muse, mutect2
- TARBP2 | c.496-26C>G | Intron (SNP) | VAF 17/223 reads (8%) | called by muse, mutect2
- TGFBR3 | c.*2876G>T | 3'UTR (SNP) | VAF 11/71 reads (15%) | catalogued as rs947802603; called by muse, mutect2, varscan2
- THADA | c.2311+268A>T | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- TRDV2 | chr14:22418485 G>C | 5'Flank (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- WDR61 | c.12+183G>C | Intron (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- XIAP | c.*2743C>G | 3'UTR (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5559C>G | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- ZNF189 | c.-61C>T | 5'UTR (SNP) | VAF 25/444 reads (6%) | called by muse, mutect2
- ZNF30 | c.-25G>A | 5'UTR (SNP) | VAF 8/76 reads (11%) | catalogued as rs746782544; called by mutect2, varscan2
- ZNF454 | c.-35G>C | 5'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- ZNF503 | c.-80G>A | 5'UTR (SNP) | VAF 54/390 reads (14%) | called by muse, mutect2, varscan2
